Somatic mutation profile of tumor specimen TCGA-CV-7238-01A (aliquot TCGA-CV-7238-01A-11D-2012-08) from TCGA case TCGA-CV-7238, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 69.7 years (25,471 days).
Specimen TCGA-CV-7238-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c6b4d07-5d30-4d57-876d-7448a8664dff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7238-10A (Blood Derived Normal), aliquot TCGA-CV-7238-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc8bdc37-868b-4c88-bee5-928e94a10eff

The open-access MAF lists 53 somatic variants for this specimen: 38 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 13, Nonsense Mutation 6, Frame Shift Del 1, In Frame Del 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 31/100 reads (31%) | catalogued as rs786204928, CM992426, COSV64292229; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by mutect2, varscan2
- ADAMTS9 | c.4087G>A p.A1363T | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.305); catalogued as rs763361579, COSV99899811; called by muse, mutect2, varscan2
- ADCY1 | c.1606C>T p.R536W | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs143601874, COSV52029598, COSV52031488; called by muse, mutect2, varscan2
- AMER1 | c.2824C>T p.R942* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as rs1404477878, COSV57657623; called by muse, mutect2, varscan2
- APOA5 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | catalogued as rs781109287, COSV99911196, COSV99911379; called by mutect2, varscan2
- ARHGEF6 | c.2080G>T p.E694* | Nonsense Mutation (SNP) | VAF 15/199 reads (8%) | catalogued as COSV99166552; called by muse, mutect2
- AVPR1A | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV54547673; called by muse, mutect2
- C10orf71 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.154); catalogued as COSV100110369, COSV60504579; called by muse, mutect2, varscan2
- C2orf16 | c.2270G>A p.G757E | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100820868; called by muse, mutect2
- COPB2 | c.2248C>T p.R750W | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773210109, COSV60351510; called by muse, mutect2, varscan2
- CSF3R | c.1283G>A p.R428K | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV100117930; called by muse, mutect2
- CSPP1 | c.665G>A p.G222D (on ENST00000676605; = p.G181D on NM_024790.6) | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.272); catalogued as rs1015362150, COSV99139033; called by muse, mutect2
- DMD | c.5307C>A p.H1769Q | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as CD068544, COSV100820852; called by muse, mutect2
- DNAH9 | c.9742C>T p.P3248S | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.612); catalogued as COSV99306759; called by muse, mutect2
- FXYD5 | c.521G>T p.R174L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV100732710; called by mutect2, varscan2
- FYB1 | c.1750C>A p.P584T | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV100685838; called by muse, mutect2, varscan2
- GFM1 | c.1802G>C p.G601A | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99962996; called by muse, mutect2, varscan2
- GSAP | c.2506G>A p.D836N | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.34); catalogued as COSV57528935; called by muse, mutect2
- HERC1 | c.6101C>T p.S2034F | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV101496707; called by muse, mutect2, varscan2
- IDI1 | c.654G>C p.L218F | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV67281698; called by muse, mutect2, varscan2
- KCNQ3 | c.1490C>T p.A497V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.146); catalogued as rs1048969639, COSV101196254, COSV66485231; called by muse, mutect2, varscan2
- KMT2A | c.9259C>T p.P3087S | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100629249; called by muse, mutect2, varscan2
- LAMA2 | c.4160C>T p.S1387F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV101370620; called by mutect2, varscan2
- LILRB2 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.31); catalogued as rs761388388, COSV100079466; called by muse, mutect2
- MAP3K14 | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV100766515; called by muse, mutect2, varscan2
- MASP2 | c.1570A>G p.T524A | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as COSV99534343; called by muse, mutect2
- NOTCH1 | c.2407C>T p.Q803* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as COSV53033985; called by muse, mutect2, varscan2
- SAMD9 | c.3598G>A p.E1200K | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV101180307, COSV101180308; called by muse, mutect2, varscan2
- SCN9A | c.1589C>T p.S530F | Missense Mutation (SNP) | VAF 32/364 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.831); catalogued as COSV100313435, COSV57610049; called by muse, mutect2
- SORBS2 | c.1069G>A p.G357S | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV53006861; called by muse, mutect2
- SPATA9 | c.9C>G p.I3M | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV99174161; called by muse, mutect2, varscan2
- SSH2 | c.4121T>A p.V1374E | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV99282488; called by muse, mutect2, varscan2
- TMEM266 | c.349C>G p.L117V | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.111); catalogued as COSV101189636; called by muse, mutect2
- TMEM70 | c.402A>C p.E134D | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV100384150; called by muse, mutect2, varscan2
- TSPEAR | c.853T>C p.F285L | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1555915249, COSV100554482; called by mutect2, varscan2
- FAT1 | c.8375_8377del p.S2792_V2793delinsL | In Frame Del (DEL) | VAF 29/242 reads (12%) | called by mutect2, pindel*
- NEK1 | c.66del p.K22Nfs*37 | Frame Shift Del (DEL) | VAF 18/169 reads (11%) | called by mutect2, pindel, varscan2
- ARID1A | c.3948G>A p.S1316= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs1265668359, COSV100250056; called by muse, varscan2
- ATP11A | c.972G>A p.R324= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV99369241; called by muse, mutect2, varscan2
- BBS9 | c.24T>C p.D8= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV99629068; called by muse, mutect2
- BRINP1 | c.2259G>A p.S753= | Silent (SNP) | VAF 28/199 reads (14%) | catalogued as rs200802804, COSV56308395; called by muse, varscan2
- CNTN3 | c.1986A>T p.V662= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as COSV99725213; called by muse, mutect2
- FOXG1 | c.1029C>T p.S343= | Silent (SNP) | VAF 20/155 reads (13%) | catalogued as COSV100486925; called by muse, mutect2, varscan2
- IGKV1D-8 | c.72C>A p.I24= | Silent (SNP) | VAF 14/180 reads (8%) | catalogued as rs112036184; called by muse, mutect2
- KIF4A | c.39G>A p.A13= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV99516353; called by mutect2, varscan2
- RUBCN | c.2685G>A p.Q895= | Silent (SNP) | VAF 24/232 reads (10%) | catalogued as COSV99583160, COSV99584496; called by muse, mutect2
- TAS2R40 | c.75C>T p.S25= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs761646828, COSV101283013; called by muse, mutect2, varscan2
- TNXB | c.7512G>A p.K2504= (on ENST00000647633; = p.K2257= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs766236096, COSV100926441; called by muse, mutect2, varscan2
- TRH | c.621C>T p.G207= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100234881; called by mutect2, varscan2
- VWA3A | c.3039G>A p.V1013= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100241084; called by muse, mutect2, varscan2
- DLG2 | c.205-65708G>A | Intron (SNP) | VAF 16/169 reads (9%) | catalogued as rs868658757, COSV54646849, COSV99717513; called by muse, mutect2
- ZNF767P | n.345G>C | RNA (SNP) | VAF 19/142 reads (13%) | called by muse, mutect2, varscan2
